Somatic mutation profile of tumor specimen C3L-01031-01 (aliquot CPT0127270006_1) from CPTAC case C3L-01031, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.1 years (23,784 days).
Specimen C3L-01031-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886dbab0-632f-4d17-9a9e-1787097a6ab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01031-31 (Blood Derived Normal), aliquot CPT0128520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acd2892-785e-4fa4-a432-42c56a94de0e

The open-access MAF lists 102 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 20, Intron 8, Splice Site 2, RNA 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 303/929 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 208/654 reads (32%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ANGPTL4 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 258/1330 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs533599788, COSV100035119, COSV100035194, COSV56845072; called by muse, mutect2, varscan2
- C10orf71 | c.4027G>A p.V1343M | Missense Mutation (SNP) | VAF 42/740 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs906410500, COSV60510676; called by muse, mutect2
- CHRNA7 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 70/2381 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs778372032; called by muse, mutect2
- COL6A1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 63/778 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.723); catalogued as rs369365801, COSV62613550; called by muse, mutect2
- CTNND2 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 200/733 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1422181938; called by muse, mutect2, varscan2
- EMX2 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 67/958 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV71294466; called by muse, mutect2
- GREB1L | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 117/907 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266822957; called by muse, mutect2, varscan2
- GSE1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 55/1071 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs199961563, COSV53670208; called by muse, mutect2
- H2BC8 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 183/534 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55127461, COSV99773400; called by muse, mutect2, varscan2
- IGSF1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 64/741 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.18); catalogued as rs778830663, CD1211168, COSV100812485; called by muse, mutect2
- KLK6 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 57/889 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565217; called by muse, mutect2
- MACF1 | c.18370G>C p.D6124H (on ENST00000372915; = p.D4169H on NM_012090.5) | Missense Mutation (SNP) | VAF 33/846 reads (4%) | catalogued as COSV99240708; called by muse, mutect2
- MUC16 | c.28520C>T p.T9507M | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs370765065; called by muse, mutect2
- NR0B1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 43/710 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as rs1361546449; called by muse, mutect2
- OCA2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 117/1392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs776631782, COSV62343363; called by muse, mutect2
- OR2M7 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 37/1135 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs899067573, COSV58738712; called by muse, mutect2
- PIGO | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 70/1076 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs775041042, COSV53055142; ClinVar: uncertain significance; called by muse, mutect2
- PLS1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61833764; called by muse, mutect2, varscan2
- RPEL1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 110/1856 reads (6%) | catalogued as rs753313707, COSV71503334; called by muse, mutect2
- RPH3A | c.1585G>A p.G529R (on ENST00000389385 / NM_001143854.2; = p.G525R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/631 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs756037748, COSV66990225; called by muse, mutect2, varscan2
- RRP12 | c.3631C>T p.Q1211* | Nonsense Mutation (SNP) | VAF 23/540 reads (4%) | catalogued as COSV100212840; called by muse, mutect2
- RTL8B | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 34/597 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV66954595; called by muse, mutect2
- RUNX1T1 | c.179C>G p.P60R (on ENST00000265814 / NM_001198628.1; = p.P33R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1195054840, COSV56152620, COSV56158222, COSV99752651; called by muse, mutect2
- SLC12A1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 62/675 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369307402, COSV101118323; called by muse, mutect2
- SLC35F4 | c.454G>A p.A152T (on ENST00000339762 / NM_001352015.2; = p.A116T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100333696; called by muse, mutect2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 90/388 reads (23%) | catalogued as rs771462597; called by mutect2, varscan2
- SPPL2A | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550930877, COSV55942276; called by muse, mutect2
- STARD9 | c.6649G>C p.E2217Q | Missense Mutation (SNP) | VAF 33/464 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); catalogued as COSV51898800; called by muse, mutect2
- TAF1L | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 64/724 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54258529; called by muse, mutect2
- TBC1D9 | c.3316G>A p.V1106M | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs545624117, COSV71308588; called by muse, mutect2, varscan2
- TDRD6 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs139956934, COSV60176261; called by muse, mutect2
- TDRD7 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 56/1048 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879227282; called by muse, mutect2
- WASHC4 | c.3427G>C p.E1143Q | Missense Mutation (SNP) | VAF 43/775 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1264820654; called by muse, mutect2
- ZFHX4 | c.9703G>A p.E3235K | Missense Mutation (SNP) | VAF 34/710 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1403930759, COSV99261375; called by muse, mutect2
- ZNF559 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as rs1389803310; called by muse, mutect2
- ACSBG2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 91/446 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAD2 | c.1550G>C p.R517P (on ENST00000315906 / NM_001145400.2; = p.R599P on NM_139174.4) | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP4B1 | c.1241A>T p.Q414L | Missense Mutation (SNP) | VAF 289/1086 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATP2B3 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 60/1096 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GALT1 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CAD | c.6397G>C p.E2133Q | Missense Mutation (SNP) | VAF 39/633 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- CMYA5 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 48/810 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.335); called by muse, mutect2
- COL4A1 | c.3054G>T p.L1018F | Missense Mutation (SNP) | VAF 398/1744 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CYP46A1 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 187/502 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- EPB41L3 | c.1694A>T p.Y565F | Missense Mutation (SNP) | VAF 20/713 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.046); called by muse, mutect2
- FSIP2 | c.6653G>A p.R2218K | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- H4C4 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 37/576 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- IL27RA | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- KCNC2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 26/784 reads (3%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.01); called by muse, mutect2
- KIAA1549L | c.394A>T p.I132L (on ENST00000321505; = p.I429L on NM_012194.3) | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 80/1444 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2
- MPHOSPH10 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MSH4 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 22/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MUC5B | c.6443A>G p.N2148S | Missense Mutation (SNP) | VAF 301/1982 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCBP1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.579); called by muse, mutect2
- NENF | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- OR2L2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 29/600 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- PNKP | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 37/696 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2
- POM121 | c.2924C>G p.A975G (on ENST00000434423; = p.A710G on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/514 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, varscan2
- PRR23C | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 17/411 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- SLC7A5 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 50/1344 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2
- TAB3 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 40/998 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TJAP1 | c.1324C>A p.L442M (on ENST00000372445 / NM_001146016.1; = p.L432M on NM_080604.3) | Missense Mutation (SNP) | VAF 109/831 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TPRG1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 25/888 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- USP24 | c.1342+1G>C p.X448_splice | Splice Site (SNP) | VAF 81/440 reads (18%) | called by muse, mutect2, varscan2
- ZIK1 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 43/874 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF182 | c.508A>G p.N170D | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- AFF2 | c.732C>T p.F244= | Silent (SNP) | VAF 38/652 reads (6%) | catalogued as rs370542676, COSV60671578; called by muse, mutect2
- ANKRD11 | c.7287C>T p.P2429= | Silent (SNP) | VAF 411/1466 reads (28%) | catalogued as rs751753158; called by muse, mutect2, varscan2
- BEND2 | c.919A>C p.R307= | Silent (SNP) | VAF 24/619 reads (4%) | called by muse, mutect2
- COL5A2 | c.3912C>T p.S1304= | Silent (SNP) | VAF 176/1189 reads (15%) | catalogued as rs571598585; called by muse, mutect2, varscan2
- DLG4 | c.1821C>T p.H607= (on ENST00000399506 / NM_001321075.3; = p.H650= on NM_001365.4) | Silent (SNP) | VAF 32/562 reads (6%) | catalogued as rs1006147091; called by muse, mutect2
- EEF1A2 | c.309C>A p.I103= | Silent (SNP) | VAF 129/544 reads (24%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2424C>T p.A808= | Silent (SNP) | VAF 15/490 reads (3%) | catalogued as rs888793473, COSV101043845; called by muse, mutect2
- KCNA1 | c.873C>T p.L291= | Silent (SNP) | VAF 36/881 reads (4%) | called by muse, mutect2
- LONRF3 | c.39C>A p.P13= | Silent (SNP) | VAF 38/784 reads (5%) | called by muse, mutect2
- MEIOC | c.1203G>A p.L401= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- MID1 | c.321C>T p.D107= | Silent (SNP) | VAF 68/363 reads (19%) | catalogued as rs754833237, COSV100452340; called by muse, mutect2, varscan2
- MUC4 | c.14433G>A p.S4811= (on ENST00000463781 / NM_018406.7; = p.S575= on NM_004532.6) | Silent (SNP) | VAF 51/1027 reads (5%) | called by muse, mutect2
- NNT | c.1449C>G p.L483= | Silent (SNP) | VAF 18/338 reads (5%) | catalogued as COSV52924967; called by muse, mutect2
- NRG2 | c.2403G>A p.A801= | Silent (SNP) | VAF 442/1476 reads (30%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1422C>G p.L474= | Silent (SNP) | VAF 94/2278 reads (4%) | called by muse, mutect2
- SRRM2 | c.4539G>A p.Q1513= | Silent (SNP) | VAF 42/1042 reads (4%) | called by muse, mutect2
- TAF4B | c.276G>A p.Q92= | Silent (SNP) | VAF 84/1200 reads (7%) | catalogued as rs780195768; called by muse, mutect2
- TGFBI | c.414C>T p.F138= | Silent (SNP) | VAF 13/341 reads (4%) | called by muse, mutect2
- TMEM72 | c.702C>T p.S234= | Silent (SNP) | VAF 91/541 reads (17%) | catalogued as COSV101273622; called by muse, mutect2, varscan2
- TRAPPC9 | c.2133A>G p.Q711= | Silent (SNP) | VAF 46/684 reads (7%) | catalogued as rs1314800707; called by muse, mutect2
- CARMIL3 | chr14:24049306 G>A | 5'Flank (SNP) | VAF 67/868 reads (8%) | called by muse, mutect2
- CDKL5 | c.2713+41G>C | Intron (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- DNAJB6 | c.346+1924T>G | Intron (SNP) | VAF 166/792 reads (21%) | called by muse, mutect2, varscan2
- GABRA1 | c.1060-28C>A | Intron (SNP) | VAF 110/429 reads (26%) | called by muse, mutect2, varscan2
- LINC02740 | n.166G>T | RNA (SNP) | VAF 93/675 reads (14%) | called by muse, mutect2, varscan2
- MIDEAS | c.*337A>G | 3'UTR (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- NBPF7 | n.643G>C | RNA (SNP) | VAF 273/1084 reads (25%) | called by muse, mutect2, varscan2
- PER1 | c.2461+90C>T | Intron (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- SREBF1 | c.524-29G>A | Intron (SNP) | VAF 56/197 reads (28%) | called by muse, mutect2, varscan2
- TPM1 | c.240+4423G>A | Intron (SNP) | VAF 20/459 reads (4%) | catalogued as COSV99147790; called by muse, mutect2
- TRADD | c.429+17G>T | Intron (SNP) | VAF 243/1758 reads (14%) | called by muse, mutect2, varscan2
- TTC39C | c.985-965A>T | Intron (SNP) | VAF 26/814 reads (3%) | called by muse, mutect2
- Y_RNA | chr7:23490630 C>T | 3'Flank (SNP) | VAF 44/759 reads (6%) | catalogued as rs1276276631; called by muse, mutect2
